Surgical pathology report (de-identified scan), TCGA case TCGA-A3-3357, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-A3-3357-01A (Primary Tumor).

[page 1 of 2]
TCGA-A3-3357

☒ TEST: Surgical Pathology

Collected Date & Time: [REDACTED]

Result Name	Results	Units	Reference Range
☒ Surgical Pathology	COPY TO:		

COPY TO:

Pre-Op Diagnosis

Renal mass

Post-Op Diagnosis

Same as above

Clinical History

Same as above

Gross Description:

Received in a single container labeled [REDACTED] right kidney is a previously bivalve right nephrectomy specimen surrounded by a large amount of perinephric adipose tissue and faced anteriorly by a moderate amount of Gerotas fascia. The specimen as received weighs 1320 grams and on reconstruction measures 25.6 x 14.0 x 8.5 cm. In the anterior superior medial aspect is a 5.1 x 2.4 x 1.0 cm recognizable adrenal gland which on sectioning has a bright yellow cortex surrounding a hyalinized tan gray medulla. The cortex has an eccentric 0.7 cm bright yellow chalky appearing nodule through the cortex in the central portion of the specimen. The margins of resection include 0.7 cm of grossly patent renal artery, 0.8 cm of grossly patent renal vein and 9.8 cm of grossly patent ureter. The capsule strips with slight difficulty to reveal to an organ measuring 12.8 x 7.0 x 6.0 cm. The cortex is lobulated, slightly pale tan brown. The cortex measures up to 1.0 cm and is slightly granular and tan brown. The corticomedullary junction is poorly defined. The medulla is gray brown and slightly hyalinized with focal blunting of the papillae. The calices and pelvis at the upper pole are grossly distorted by the presence of a 7.8 x 6.5 x 6.2 cm lobulated tan gray to yellow lesion with fleshy, slightly bulging tan yellow moderately hemorrhagic cut surface. This lesion focally appears to be slightly encapsulated and grossly appears to extend beyond the plane of the kidney proper, however, the lesion does not appear to extend into the surrounding adipose tissue being separated from it by attenuated corporal parenchyma. The lesion grossly compresses the calices and upper pelvis and does not grossly appear to extend into them. No additional gross lesions are identified. Also received in the same container are three tissue cassettes, each labeled [REDACTED]. Representative sections are submitted labeled as follows: A vascular and ureteral margins of resection; B through G representative lesion and surrounding tissue; H random uninvolved parenchyma; I representative adrenal gland.

Microscopic Description:

See diagnosis.

Final Diagnosis

Kidney, right, radical nephrectomy:

Tumor characteristics:

Histologic type: Conventional (clear cell) renal carcinoma

Tumor site: Upper pole

Tumor size: 7.8 x 6.5 x 6.2 cm

Macroscopic extent of tumor: Malignancy remains within renal capsule with no gross extension into perinephric tissues, major vessels or renal pelvis.

Nuclear grade: Fuhrman grade 3/4

Lymphovascular space invasion: Yes

Transcapsular invasion: Not identified

Renal vein invasion: Not identified

[page 2 of 2]
Vena caval invasion: Not resected
Adrenal gland: Negative for malignancy
Surgical margin status:
Soft tissue margins: Negative
Ureteral margin: Negative
Vascular margin: Negative
Lymph node status: No lymph nodes identified PAS 9 SPC-A
CPT: 88307

Comments

Histologic features confirm the prior fine needle biopsy [REDACTED].
At the request of the undersigned pathologist, these slides have been
additionally reviewed by Dr. [REDACTED], who concurs with the diagnosis.
This test has been finalized at the [REDACTED] Campus.
[REDACTED]

Source: NCI Genomic Data Commons file 3f60d6bf-c4f1-408b-8699-e0f1c0fca46c (TCGA-A3-3357.9F0F7CF4-5A7A-4C20-8123-B5164550490C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).